Somatic mutation profile of tumor specimen C3N-02721-03 (aliquot CPT0178800006) from CPTAC case C3N-02721, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 54.5 years (19,893 days).
Specimen C3N-02721-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 021b9d20-8025-4e05-a24d-89150ffcb411.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02721-71 (Blood Derived Normal), aliquot CPT0178900002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39b4c25f-92d2-4c10-9634-5c6b3afbdbe2

The open-access MAF lists 521 somatic variants for this specimen: 356 protein-altering or splice-affecting, 109 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 296, Silent 109, Nonsense Mutation 36, Intron 29, Splice Region 9, 3'UTR 8, RNA 8, Frame Shift Del 7, Splice Site 5, 5'UTR 5, 5'Flank 3, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1517G>C p.G506A (on ENST00000288602 / NM_001374244.1; = p.G466A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/249 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.1249G>T p.G417W | Missense Mutation (SNP) | VAF 17/60 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50311993, COSV99408348; called by muse, mutect2, varscan2
- LDLR | c.1730G>A p.W577* | Nonsense Mutation (SNP) | VAF 80/449 reads (18%) | catalogued as rs138947766, CM1312419, CM960937; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.2197G>T p.D733Y | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV104371215; called by muse, mutect2, varscan2
- ACSM2A | c.1019C>A p.S340Y (on ENST00000219054; = p.S261Y on NM_001308169.2) | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs765780796, COSV99525415; called by muse, mutect2
- ACVRL1 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 127/552 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as rs746430008; called by muse, mutect2, varscan2
- ADAMTS5 | c.518G>A p.W173* | Nonsense Mutation (SNP) | VAF 16/292 reads (5%) | catalogued as rs1484003560; called by muse, mutect2
- ALAS1 | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.097); catalogued as COSV100050323; called by muse, mutect2, varscan2
- ARID2 | c.3286C>T p.Q1096* | Nonsense Mutation (SNP) | VAF 56/263 reads (21%) | catalogued as COSV57610169; called by muse, mutect2, varscan2
- ATXN7 | c.2671C>T p.R891C | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs768825154; called by mutect2, varscan2
- C20orf194 | c.2426G>T p.R809L | Missense Mutation (SNP) | VAF 73/371 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs760665620; called by muse, mutect2, varscan2
- C3orf56 | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 41/329 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.104); catalogued as COSV101228929; called by muse, mutect2, varscan2
- CADM3 | c.1045A>G p.I349V (on ENST00000368125 / NM_001127173.3; = p.I383V on NM_021189.5) | Missense Mutation (SNP) | VAF 66/443 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs781519418; called by muse, mutect2, varscan2
- CALCRL | c.923del p.F308Sfs*3 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | catalogued as rs1422497140; called by mutect2, pindel
- CAND1 | c.1523A>G p.H508R | Missense Mutation (SNP) | VAF 125/252 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs772884568; called by muse, mutect2, varscan2
- CAPN5 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 43/542 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as rs746809647; called by muse, mutect2
- CASC3 | c.1973C>G p.S658* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as COSV52866516; called by muse, mutect2, varscan2
- CASP8 | c.1157C>T p.S386L (on ENST00000432109 / NM_033355.3; = p.S403L on NM_001228.4) | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as rs770193825, COSV51847483, COSV51851164; called by muse, mutect2, varscan2
- CD200R1 | c.496G>A p.V166I (on ENST00000471858 / NM_170780.3; = p.V189I on NM_138806.4) | Missense Mutation (SNP) | VAF 43/279 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV55600582; called by muse, mutect2, varscan2
- CEP128 | c.1717C>T p.H573Y | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.201); catalogued as rs772343483; called by muse, mutect2, varscan2
- CNGA1 | c.306G>T p.K102N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100652338; called by muse, mutect2, varscan2
- CNTNAP2 | c.3439A>T p.N1147Y | Missense Mutation (SNP) | VAF 62/351 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV62250305; called by muse, mutect2, varscan2
- COL4A1 | c.2951G>T p.G984V | Missense Mutation (SNP) | VAF 86/492 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65425625; called by muse, mutect2, varscan2
- COL6A5 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99591483; called by muse, mutect2, varscan2
- COL9A1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.319); catalogued as COSV61829391; called by muse, mutect2
- CPNE8 | c.1147G>T p.G383W | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs967299608; called by muse, mutect2, varscan2
- CYP2C9 | c.818A>T p.K273M | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs1482721072, CD014776, COSV53246874; called by muse, mutect2
- CYP2S1 | c.334G>C p.D112H | Missense Mutation (SNP) | VAF 80/273 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV59507353; called by muse, mutect2, varscan2
- DACH2 | c.1257A>T p.Q419H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.416); catalogued as COSV64182559; called by muse, mutect2, varscan2
- DENND10 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 32/476 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1195381558; called by muse, mutect2
- DKK2 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.14); catalogued as rs1327013466; called by muse, mutect2
- DLK1 | c.1152A>T p.*384Yext*23 | Nonstop Mutation (SNP) | VAF 3/33 reads (9%) | catalogued as COSV100375489; called by muse, mutect2
- DOCK10 | c.4076G>C p.R1359T | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51412465; called by muse, mutect2, varscan2
- DPP6 | c.413G>T p.S138I (on ENST00000377770 / NM_001364500.2; = p.S76I on NM_001936.5) | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as COSV100125588; called by muse, mutect2
- DRD2 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 40/169 reads (24%) | catalogued as COSV60755235; called by muse, mutect2, varscan2
- ERN2 | c.432G>C p.Q144H | Missense Mutation (SNP) | VAF 66/379 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV56833610; called by muse, mutect2, varscan2
- EXT1 | c.986A>C p.H329P | Missense Mutation (SNP) | VAF 75/453 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs755363067; called by muse, mutect2, varscan2
- EYA4 | c.1001C>T p.T334I (on ENST00000531901 / NM_001301013.1; = p.T328I on NM_004100.5) | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.251); catalogued as rs897811426; called by muse, mutect2
- FAM216B | c.12C>A p.N4K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs777435097; called by muse, mutect2, varscan2
- FAM83E | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 91/261 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as rs1568420921, COSV54367936, COSV99613688; called by muse, mutect2, varscan2
- FILIP1 | c.3143C>T p.T1048I | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.04); catalogued as COSV52734805; called by muse, mutect2, varscan2
- FSCB | c.1361C>A p.P454H | Missense Mutation (SNP) | VAF 42/318 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as COSV61218725; called by muse, mutect2, varscan2
- FSIP2 | c.18266A>G p.Y6089C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100556476; called by muse, mutect2, varscan2
- GABRB3 | c.1208G>T p.R403M | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as COSV54649775; called by muse, mutect2, varscan2
- HEPH | c.3164G>T p.G1055V (on ENST00000343002; = p.G788V on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1320619755, COSV100295161; called by muse, mutect2, varscan2
- HHIPL2 | c.1614G>T p.K538N | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV58566647; called by muse, mutect2, varscan2
- HMCN1 | c.4447C>G p.P1483A | Missense Mutation (SNP) | VAF 72/297 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54891094; called by muse, mutect2, varscan2
- IRF6 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM034818, COSV100883988, COSV65419171; called by muse, mutect2, varscan2
- KANSL1 | c.1916G>T p.G639V | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as COSV99294929; called by muse, mutect2, varscan2
- KCNB2 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as COSV101578769, COSV73052577; called by muse, mutect2
- KCNK9 | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV57286418; called by muse, mutect2, varscan2
- KDM5C | c.2062-1G>T p.X688_splice | Splice Site (SNP) | VAF 50/159 reads (31%) | catalogued as COSV64766857; called by muse, mutect2, varscan2
- KIRREL2 | c.1217C>A p.S406Y | Missense Mutation (SNP) | VAF 87/318 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.564); catalogued as COSV52877183; called by muse, mutect2, varscan2
- KMT5B | c.1317G>T p.K439N | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58569715; called by muse, mutect2, varscan2
- KPRP | c.1184C>A p.P395Q | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV64222735; called by muse, mutect2, varscan2
- KRT1 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 30/501 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52866540; called by muse, mutect2
- LCE2A | c.187G>T p.G63W | Missense Mutation (SNP) | VAF 126/524 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1474103209; called by muse, mutect2, varscan2
- LRRC8D | c.1744G>C p.E582Q | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.695); catalogued as rs1273444877; called by muse, mutect2
- LRRTM1 | c.1141C>A p.R381S | Missense Mutation (SNP) | VAF 35/280 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV54446221; called by muse, mutect2, varscan2
- MGAM | c.3317G>T p.W1106L | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.776); catalogued as COSV72074912; called by muse, mutect2
- MGAT4A | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53851138; called by muse, varscan2
- MRNIP | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs562422912, COSV52975381; called by muse, mutect2, varscan2
- MS4A14 | c.1073A>T p.Q358L | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV55732788; called by muse, mutect2, varscan2
- MTTP | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.185); catalogued as COSV55509869; called by muse, mutect2
- MYO3B | c.2063A>T p.Y688F | Missense Mutation (SNP) | VAF 87/569 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58715053; called by muse, mutect2, varscan2
- NEK1 | c.3269G>T p.G1090V | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV71457109; called by muse, mutect2
- NHLRC1 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 66/512 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1217000055, COSV104415836; called by muse, varscan2
- NSD1 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 83/399 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.068); catalogued as rs1373466948, COSV100728603; called by muse, mutect2, varscan2
- NTF4 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 64/215 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as rs1025529881, COSV56824622; called by muse, mutect2, varscan2
- OR52E4 | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV57623761; called by muse, mutect2, varscan2
- OR5AP2 | c.796T>A p.L266M | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100266291; called by muse, mutect2, varscan2
- OR8B4 | c.804C>G p.N268K | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV62069312; called by muse, mutect2, varscan2
- OR8B8 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 47/318 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); catalogued as rs371008288; called by muse, mutect2, varscan2
- P3H1 | c.1371C>G p.I457M | Missense Mutation (SNP) | VAF 34/460 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs964500877; called by muse, mutect2
- PDE10A | c.2239C>G p.P747A | Missense Mutation (SNP) | VAF 75/237 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs539276206; called by muse, mutect2, varscan2
- PDGFRA | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs587778598, COSV57265859; ClinVar: likely benign / uncertain significance / not provided; called by muse, mutect2, varscan2
- PLXNA4 | c.922C>G p.R308G | Missense Mutation (SNP) | VAF 36/392 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58135749; called by muse, mutect2
- POTEC | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 74/673 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62800597, COSV62801210; called by muse, mutect2, varscan2
- PRKCI | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs775812965, COSV99856257; called by muse, mutect2, varscan2
- PTPRD | c.4817del p.H1606Lfs*5 | Frame Shift Del (DEL) | VAF 22/188 reads (12%) | catalogued as COSV61981346; called by mutect2, pindel*, varscan2*
- RABL6 | c.2018G>A p.S673N | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.074); catalogued as rs1243362275; called by muse, mutect2
- RAD9A | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1349227530; called by muse, mutect2, varscan2
- RBM44 | c.1210A>G p.I404V (on ENST00000611254; = p.I1038V on NM_001080504.2) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1447634145; called by muse, mutect2, varscan2
- RBMXL2 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs1407591648; called by muse, mutect2, varscan2
- RICTOR | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV57121658; called by muse, mutect2, varscan2
- SCAPER | c.4097A>G p.K1366R | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1418308199; called by muse, mutect2, varscan2
- SCAPER | c.-62G>T | Splice Region (SNP) | VAF 13/39 reads (33%) | catalogued as rs923376769; called by muse, mutect2, varscan2
- SCARF2 | c.1645C>T p.R549W | Missense Mutation (SNP) | VAF 46/280 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs767274143; called by muse, mutect2, varscan2
- SCN2A | c.3092G>T p.R1031M | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as COSV99333436; called by muse, mutect2, varscan2
- SCN7A | c.4948G>A p.D1650N | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV69270401, COSV69272984; called by muse, mutect2, varscan2
- SERINC1 | c.837G>A p.M279I | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as rs1347592803; called by mutect2, varscan2
- SLC30A2 | c.233C>G p.S78C | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as rs757131894, COSV65333536; called by muse, mutect2, varscan2
- SLC5A1 | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 16/506 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs868062241, COSV56688389; called by muse, mutect2
- SLC6A19 | c.774+1G>T p.X258_splice | Splice Site (SNP) | VAF 75/543 reads (14%) | catalogued as rs554777392; called by muse, mutect2, varscan2
- SLC9B1 | c.1135C>G p.L379V | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV56467414; called by muse, mutect2
- SLITRK3 | c.2015C>A p.A672E | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99578548; called by muse, mutect2, varscan2
- SPAG16 | c.868G>T p.G290C | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55984130; called by muse, mutect2, varscan2
- SPDYC | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as rs1237360422; called by muse, mutect2
- SPOCD1 | c.1914G>T p.E638D | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV99930403; called by muse, mutect2
- SPTA1 | c.6447G>T p.E2149D | Missense Mutation (SNP) | VAF 59/546 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.416); catalogued as COSV63748485; called by muse, varscan2
- SSBP1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.062); catalogued as rs1295747049; called by muse, mutect2, varscan2
- SV2C | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100455992; called by muse, varscan2
- SZT2 | c.9632G>A p.R3211H (on ENST00000634258 / NM_001365999.1; = p.R3154H on NM_015284.4) | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374492072; called by muse, mutect2, varscan2
- TAF2 | c.3038C>T p.S1013L | Missense Mutation (SNP) | VAF 27/325 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs769931799; called by muse, mutect2
- TAS1R3 | c.2042C>A p.A681D | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100229721; called by muse, mutect2, varscan2
- TAS2R10 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as COSV53701054; called by muse, mutect2, varscan2
- TENM4 | c.5459C>A p.A1820D | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs373584472; called by muse, mutect2
- TLE2 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1310242637; called by muse, mutect2, varscan2
- TNR | c.2652G>T p.W884C | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54899542; called by muse, mutect2, varscan2
- TP53 | c.871A>T p.K291* | Nonsense Mutation (SNP) | VAF 187/685 reads (27%) | catalogued as COSV52761043, COSV52809147, COSV52984891; called by muse, mutect2, varscan2
- TRIML1 | c.86C>A p.T29N | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV60197781; called by muse, mutect2
- TSC1 | c.555C>G p.Y185* | Nonsense Mutation (SNP) | VAF 29/398 reads (7%) | catalogued as COSV53765068, COSV53765773, COSV53771625, COSV53775014; called by muse, mutect2
- TXNRD3 | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV73119954; called by muse, mutect2
- U2AF2 | c.12C>G p.F4L | Missense Mutation (SNP) | VAF 151/456 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV58274301; called by muse, mutect2, varscan2
- UCKL1 | c.1389G>C p.M463I | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1307471845; called by muse, mutect2
- XIRP2 | c.7678C>A p.Q2560K (on ENST00000628543; = p.Q2735K on NM_152381.6) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV99738672; called by muse, mutect2
- XKR6 | c.1505G>T p.G502V | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99059255; called by muse, mutect2, varscan2
- ZIC1 | c.1012G>T p.G338C | Missense Mutation (SNP) | VAF 55/335 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51553757; called by muse, mutect2, varscan2
- ZNF765 | c.1210C>G p.L404V | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as rs1249280149; called by muse, mutect2
- A2M | c.3125C>A p.T1042K | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCB7 | c.1565A>G p.Y522C (on ENST00000373394 / NM_001271696.3; = p.Y523C on NM_004299.6) | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ABHD16B | c.440C>A p.A147D | Missense Mutation (SNP) | VAF 42/307 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AC073316.1 | n.199G>T | Splice Region (SNP) | VAF 36/190 reads (19%) | called by muse, mutect2, varscan2
- AC097636.1 | c.158T>A p.L53Q | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC138647.1 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 21/256 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); called by muse, mutect2
- ACE | c.452A>G p.Y151C | Missense Mutation (SNP) | VAF 100/482 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACSM1 | c.385G>C p.V129L | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.028); called by muse, mutect2
- ADAM23 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ADAM23 | c.2324G>T p.R775M | Missense Mutation (SNP) | VAF 31/233 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- ADAMTS20 | c.3529G>T p.V1177L | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ADAMTSL3 | c.3188G>C p.C1063S | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ADAT1 | c.658A>G p.K220E | Missense Mutation (SNP) | VAF 72/448 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADCY3 | c.943C>A p.H315N | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADCY8 | c.2848A>T p.M950L | Missense Mutation (SNP) | VAF 48/342 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- AGMO | c.535C>A p.L179I | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ALK | c.3694G>T p.D1232Y | Missense Mutation (SNP) | VAF 50/327 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK2 | c.8677C>G p.Q2893E | Missense Mutation (SNP) | VAF 57/413 reads (14%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.11245G>A p.V3749I | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); called by muse, mutect2
- ANKRD24 | c.1184T>A p.L395Q | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANO3 | c.206C>A p.S69Y | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASPN | c.475C>A p.H159N | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- ATMIN | c.2334G>C p.L778F | Missense Mutation (SNP) | VAF 44/298 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ATP2B3 | c.2463G>C p.E821D | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ATPSCKMT | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AUTS2 | c.3000C>G p.H1000Q | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.022); called by muse, mutect2
- BAZ1B | c.560G>A p.R187K | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.108); called by muse, mutect2
- BCAS1 | c.1226T>C p.V409A | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- BICDL1 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.225); called by muse, mutect2
- CALD1 | c.1888G>A p.D630N (on ENST00000361675 / NM_033138.4; = p.D375N on NM_004342.7) | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2
- CBY2 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 20/90 reads (22%) | called by muse, mutect2, varscan2
- CCDC144A | c.3847G>C p.E1283Q | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- CCDC33 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2
- CCNT2 | c.535A>G p.N179D | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CDH16 | c.1173C>G p.F391L | Missense Mutation (SNP) | VAF 19/352 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDH2 | c.1807C>A p.P603T | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDK14 | c.550C>G p.L184V (on ENST00000380050 / NM_001287135.2; = p.L166V on NM_012395.3) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- CEND1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CEP128 | c.2957G>T p.R986I | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- CFAP91 | c.604A>T p.T202S | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CHCHD3 | c.224C>G p.A75G | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.583); called by muse, mutect2
- CHUK | c.1929G>C p.Q643H | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2
- CLHC1 | c.1170del p.T391Hfs*5 | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | called by mutect2, pindel, varscan2
- CNTN1 | c.2846A>C p.Q949P | Missense Mutation (SNP) | VAF 54/330 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- CNTN6 | c.3073C>T p.Q1025* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.1782C>A p.Y594* | Nonsense Mutation (SNP) | VAF 22/138 reads (16%) | called by muse, mutect2, varscan2
- COG8 | c.86C>A p.S29* | Nonsense Mutation (SNP) | VAF 40/609 reads (7%) | called by muse, mutect2
- COLEC10 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COLEC11 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 58/453 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CPS1 | c.2786G>T p.R929M | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.6709_6710del p.G2237* (on ENST00000297405 / NM_001363185.1; = p.G2133* on NM_052900.3) | Frame Shift Del (DEL) | VAF 12/105 reads (11%) | called by mutect2, pindel*
- CSMD3 | c.664dup p.S222Ffs*3 | Frame Shift Ins (INS) | VAF 20/213 reads (9%) | called by mutect2, pindel, varscan2
- CSRNP3 | c.1059C>A p.C353* | Nonsense Mutation (SNP) | VAF 47/268 reads (18%) | called by muse, mutect2, varscan2
- CTBP1 | c.1020A>T p.T340= | Splice Region (SNP) | VAF 49/280 reads (18%) | called by muse, mutect2, varscan2
- CTDP1 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 30/371 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP1B1 | c.1043+5_1043+6insAC | Splice Region (INS) | VAF 34/280 reads (12%) | called by mutect2, pindel, varscan2
- DAB1 | c.1150C>T p.Q384* (on ENST00000371231; = p.Q351* on NM_021080.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 75/234 reads (32%) | called by muse, mutect2, varscan2
- DGKI | c.1346A>T p.Q449L | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.066); called by muse, mutect2
- DLGAP3 | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNM2 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 65/441 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- EARS2 | c.508A>G p.M170V | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, varscan2
- ELFN1 | c.2291C>T p.S764F | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- EOLA1 | c.126C>A p.H42Q | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- EPB41L2 | c.1239C>T p.D413= | Splice Region (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- EPS8L2 | c.1560_1560+1insA p.V521Sfs*250 | Frame Shift Ins (INS) | VAF 32/281 reads (11%) | called by pindel, varscan2
- ESR2 | c.617T>A p.L206H | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EXOC3L1 | c.2134C>A p.R712S | Missense Mutation (SNP) | VAF 40/357 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EXPH5 | c.2256G>C p.K752N | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- FAM200A | c.586C>G p.L196V | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- FGF2 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 23/298 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- FGR | c.227-1G>T p.X76_splice | Splice Site (SNP) | VAF 15/139 reads (11%) | called by muse, mutect2, varscan2
- FLG2 | c.2866G>T p.G956C | Missense Mutation (SNP) | VAF 60/564 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- FOXO1 | c.134C>A p.S45* | Nonsense Mutation (SNP) | VAF 14/131 reads (11%) | called by muse, mutect2, varscan2
- FREM2 | c.1897G>T p.G633W | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- GAL3ST4 | c.344G>C p.R115T | Missense Mutation (SNP) | VAF 29/261 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GATA1 | c.625G>C p.A209P | Missense Mutation (SNP) | VAF 26/468 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GCSAM | c.321T>A p.Y107* | Nonsense Mutation (SNP) | VAF 40/328 reads (12%) | called by muse, mutect2, varscan2
- GJA10 | c.834A>T p.E278D | Missense Mutation (SNP) | VAF 55/275 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GLB1L2 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2, varscan2
- GLI1 | c.2275A>T p.T759S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GLRX3 | c.159G>T p.M53I | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- GPC5 | c.22G>C p.V8L | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPR173 | c.984G>T p.M328I | Missense Mutation (SNP) | VAF 17/267 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2
- GRID1 | c.2240A>T p.E747V | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GRXCR1 | c.809A>T p.K270I | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.995); called by muse, mutect2
- GTF3C4 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- HLA-DMB | c.776-6C>T | Splice Region (SNP) | VAF 17/133 reads (13%) | called by muse, mutect2, varscan2
- HMGA2 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 15/402 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- HNRNPUL1 | c.887-2A>G p.X296_splice | Splice Site (SNP) | VAF 54/170 reads (32%) | called by muse, mutect2, varscan2
- IGHMBP2 | c.2680G>A p.D894N | Missense Mutation (SNP) | VAF 54/371 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- IGHV3-38 | c.175G>C p.A59P | Missense Mutation (SNP) | VAF 24/391 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.35); called by muse, mutect2
- IGHV3OR16-8 | c.88T>A p.L30M | Missense Mutation (SNP) | VAF 23/290 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- IMPA1 | c.783G>T p.R261S | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.34); PolyPhen probably damaging (1); called by muse, mutect2
- INSYN1 | c.807G>C p.Q269H | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IRF2BP1 | c.10G>C p.V4L | Missense Mutation (SNP) | VAF 110/418 reads (26%) | SIFT tolerated (0.99); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- IRF2BPL | c.1198G>T p.G400C | Missense Mutation (SNP) | VAF 39/380 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JPH3 | c.1475C>A p.P492H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- KCNH5 | c.228G>T p.K76N | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2
- KCNQ2 | c.250G>T p.V84L | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- KIAA1109 | c.643G>T p.G215* | Nonsense Mutation (SNP) | VAF 22/155 reads (14%) | called by muse, mutect2, varscan2
- KLF13 | c.620A>T p.K207M | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KLHL3 | c.497A>C p.D166A | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- KLK13 | c.597C>G p.D199E | Missense Mutation (SNP) | VAF 71/290 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KNG1 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 59/383 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- KRT26 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 84/488 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- LHX3 | c.1051G>T p.A351S (on ENST00000371748 / NM_178138.6; = p.A356S on NM_014564.5) | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- LIG4 | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LMF1 | c.874G>T p.G292W | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1B | c.13067G>T p.C4356F | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- LRRC15 | c.1110C>G p.I370M | Missense Mutation (SNP) | VAF 26/434 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- LTBP2 | c.1023G>A p.G341= | Splice Region (SNP) | VAF 38/345 reads (11%) | called by muse, mutect2, varscan2
- MACC1 | c.1660G>T p.G554W | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MACF1 | c.20047G>A p.E6683K (on ENST00000372915; = p.E4728K on NM_012090.5) | Missense Mutation (SNP) | VAF 12/230 reads (5%) | called by muse, mutect2
- MAFB | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MAGEB3 | c.63G>T p.Q21H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- MAGEB4 | c.956C>A p.P319H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.147); called by muse, mutect2
- MAGI1 | c.3330C>G p.F1110L (on ENST00000402939 / NM_001033057.2; = p.F1139L on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.195); called by muse, mutect2
- MAOA | c.559C>G p.H187D | Missense Mutation (SNP) | VAF 21/650 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2
- MAP4K3 | c.2168G>C p.R723T | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- MARCHF7 | c.1375A>G p.T459A | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- MBD6 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MDGA1 | c.267C>A p.F89L | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MED14 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 14/208 reads (7%) | called by muse, mutect2
- MEP1B | c.463C>A p.L155I | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MGAM | c.2207C>A p.T736K | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMRN1 | c.1956G>C p.L652F | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.484); called by muse, mutect2
- MPV17L | c.277G>C p.G93R | Missense Mutation (SNP) | VAF 42/302 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- MST1R | c.3463G>T p.G1155C | Missense Mutation (SNP) | VAF 53/292 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MTAP | c.860A>G p.N287S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTTP | c.942C>A p.Y314* | Nonsense Mutation (SNP) | VAF 24/342 reads (7%) | called by muse, mutect2
- MUC16 | c.11782C>A p.P3928T | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MYLK | c.5426C>A p.P1809H | Missense Mutation (SNP) | VAF 42/253 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAPEPLD | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- NARF | c.909C>A p.F303L | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.452); called by muse, mutect2
- NAV3 | c.2890G>T p.V964L | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCALD | c.310_335del p.A104Kfs*18 | Frame Shift Del (DEL) | VAF 18/180 reads (10%) | called by mutect2, pindel
- NEURL1 | c.4G>A p.G2S | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NFKBIL1 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- NHS | c.1429G>T p.V477L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- NKAIN2 | c.244T>G p.F82V | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NOTCH4 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 29/283 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2
- NPAP1 | c.3125A>G p.Q1042R | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- NPEPPS | c.2095G>C p.G699R | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- NPHP3 | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NPY2R | c.667T>A p.S223T | Missense Mutation (SNP) | VAF 27/377 reads (7%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2
- NT5C1B | c.442C>A p.P148T (on ENST00000359846 / NM_001199086.2; = p.P88T on NM_033253.4) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- NUB1 | c.1468-1G>C p.X490_splice (on ENST00000568733 / NM_001243351.1; = p.X476_splice on NM_016118.4) | Splice Site (SNP) | VAF 23/139 reads (17%) | called by muse, mutect2, varscan2
- NXPH4 | c.787C>G p.Q263E | Missense Mutation (SNP) | VAF 135/561 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OR2AJ1 | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.119); called by muse, mutect2
- OR2Z1 | c.7del p.D3? | Frame Shift Del (DEL) | VAF 23/105 reads (22%) | called by mutect2, pindel, varscan2
- OR5V1 | c.325G>T p.G109* | Nonsense Mutation (SNP) | VAF 42/297 reads (14%) | called by muse, mutect2, varscan2
- OTUD1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT tolerated (0.85); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- P2RY13 | c.44C>A p.P15Q | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2
- P4HA1 | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2
- PALMD | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- PAPLN | c.1112G>T p.W371L (on ENST00000554301; = p.W344L on NM_173462.4) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PAPPA2 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 66/302 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- PAPPA2 | c.1550G>A p.W517* | Nonsense Mutation (SNP) | VAF 56/291 reads (19%) | called by muse, mutect2, varscan2
- PCLO | c.12919A>T p.R4307W | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCNX2 | c.5650G>T p.E1884* | Nonsense Mutation (SNP) | VAF 10/345 reads (3%) | called by muse, mutect2
- PIDD1 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- PIM1 | c.64G>C p.A22P | Missense Mutation (SNP) | VAF 59/382 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PITPNM1 | c.3502G>C p.G1168R | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- PITPNM3 | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 77/272 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1L1 | c.160del p.E54Kfs*24 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
- PLA2G4A | c.784A>T p.N262Y | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PLEKHH2 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.755); called by muse, mutect2
- PLP2 | c.23C>A p.S8* | Nonsense Mutation (SNP) | VAF 43/281 reads (15%) | called by muse, mutect2, varscan2
- POU3F3 | c.1151T>C p.L384P | Missense Mutation (SNP) | VAF 63/511 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R12B | c.113G>C p.R38P | Missense Mutation (SNP) | VAF 87/343 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPP1R16A | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 73/412 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R16B | c.1388C>A p.A463D | Missense Mutation (SNP) | VAF 95/692 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PPP2R1A | c.1568C>A p.P523H | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PRKN | c.596C>A p.P199Q | Missense Mutation (SNP) | VAF 28/459 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2
- PRPF6 | c.1017C>G p.C339W | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2
- PTCHD4 | c.241G>C p.A81P | Missense Mutation (SNP) | VAF 47/296 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PUM2 | c.1762C>G p.L588V | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- PXDN | c.2347C>G p.P783A | Missense Mutation (SNP) | VAF 46/760 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2
- QTRT2 | c.410A>T p.Q137L | Missense Mutation (SNP) | VAF 44/373 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- RGSL1 | c.2632G>A p.A878T | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.054); called by muse, mutect2
- RHCG | c.940G>T p.G314C | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RLN1 | c.512G>T p.C171F | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- RNF207 | c.1341G>T p.E447D | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SEMA3D | c.661C>A p.P221T | Missense Mutation (SNP) | VAF 24/249 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.075); called by muse, mutect2
- SEMA5A | c.3128T>C p.I1043T | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- SEMA5B | c.2324G>T p.R775L | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- SEMA6D | c.2875G>T p.E959* (on ENST00000316364 / NM_153618.2; = p.E897* on NM_020858.2) | Nonsense Mutation (SNP) | VAF 19/118 reads (16%) | called by muse, mutect2, varscan2
- SERPINA10 | c.614T>A p.M205K | Missense Mutation (SNP) | VAF 46/391 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- SETDB1 | c.1302C>G p.Y434* | Nonsense Mutation (SNP) | VAF 47/177 reads (27%) | called by muse, mutect2, varscan2
- SLC16A11 | c.563T>A p.L188H (on ENST00000308009; = p.L164H on NM_153357.3) | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC25A52 | c.859C>T p.H287Y (on ENST00000672005; = p.H277Y on NM_001034172.4) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.95); PolyPhen benign (0.012); called by muse, varscan2
- SLC44A5 | c.1185G>C p.L395F | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SLC44A5 | c.1184T>A p.L395* | Nonsense Mutation (SNP) | VAF 46/188 reads (24%) | called by muse, mutect2, varscan2
- SLC4A4 | c.796G>C p.E266Q (on ENST00000264485 / NM_001098484.3; = p.E222Q on NM_003759.4) | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.027); called by muse, mutect2
- SMARCD1 | c.303G>T p.K101N | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- SMYD4 | c.715G>T p.V239L | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNX14 | c.1181A>G p.Q394R (on ENST00000314673 / NM_001350535.1; = p.Q350R on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOGA1 | c.2355G>T p.R785S | Missense Mutation (SNP) | VAF 60/309 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- SPINT4 | c.283T>A p.Y95N | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- SPRR2A | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPTBN1 | c.5967G>T p.K1989N | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); called by muse, varscan2
- SULT1C4 | c.323C>A p.S108* | Nonsense Mutation (SNP) | VAF 39/273 reads (14%) | called by muse, mutect2, varscan2
- SVEP1 | c.1399G>T p.D467Y | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- TAF10 | c.388-3C>G | Splice Region (SNP) | VAF 31/189 reads (16%) | called by muse, mutect2, varscan2
- TAS2R43 | c.366G>C p.K122N | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- TBX5 | c.1117G>T p.A373S | Missense Mutation (SNP) | VAF 87/545 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by mutect2, varscan2
- TDRD6 | c.1163G>A p.W388* | Nonsense Mutation (SNP) | VAF 22/161 reads (14%) | called by muse, mutect2, varscan2
- TET1 | c.5273G>T p.R1758M | Missense Mutation (SNP) | VAF 23/374 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- TFAP2A | c.1201C>T p.Q401* (on ENST00000482890; = p.Q393* on NM_001032280.3) | Nonsense Mutation (SNP) | VAF 56/530 reads (11%) | called by muse, mutect2, varscan2
- TLR5 | c.770C>G p.S257C | Missense Mutation (SNP) | VAF 73/298 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TMEM181 | c.1411C>T p.Q471* | Nonsense Mutation (SNP) | VAF 46/178 reads (26%) | called by muse, mutect2, varscan2
- TMEM198 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- TPSB2 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRBV19 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.359); called by muse, varscan2
- TREML1 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 47/342 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM64C | c.1322T>G p.L441R | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTC27 | c.1381C>T p.Q461* | Nonsense Mutation (SNP) | VAF 22/226 reads (10%) | called by muse, mutect2
- TTN | c.74561A>C p.H24854P (on ENST00000591111; = p.H17430P on NM_003319.4) | Missense Mutation (SNP) | VAF 25/195 reads (13%) | PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- TTN | c.23573A>G p.K7858R (on ENST00000591111; = p.K6931R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | PolyPhen benign (0.111); called by muse, mutect2, varscan2
- UBALD2 | c.121-6C>G | Splice Region (SNP) | VAF 56/816 reads (7%) | called by muse, mutect2
- UGGT1 | c.2434A>G p.R812G | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- UGT8 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 29/195 reads (15%) | called by muse, mutect2, varscan2
- UNC93A | c.1169G>A p.W390* | Nonsense Mutation (SNP) | VAF 122/371 reads (33%) | called by muse, mutect2, varscan2
- VANGL2 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 78/351 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VCL | c.2792C>G p.A931G | Missense Mutation (SNP) | VAF 28/519 reads (5%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.031); called by muse, mutect2
- WDR70 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 12/335 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.022); called by muse, mutect2
- XKR6 | c.398T>A p.V133E | Missense Mutation (SNP) | VAF 32/418 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2
- ZDHHC6 | c.944G>C p.S315T | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, varscan2
- ZER1 | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFHX3 | c.4583G>C p.R1528T | Missense Mutation (SNP) | VAF 9/242 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZFHX4 | c.8513C>T p.S2838F | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- ZFYVE26 | c.5618A>T p.K1873I | Missense Mutation (SNP) | VAF 49/374 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ZNF365 | c.561G>C p.L187F | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF462 | c.5732T>A p.L1911* | Nonsense Mutation (SNP) | VAF 10/238 reads (4%) | called by muse, mutect2
- ZNF510 | c.1031A>G p.N344S | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF594 | c.1313G>T p.G438V | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZP3 | c.1196C>T p.S399F (on ENST00000394857 / NM_001110354.2; = p.S348F on NM_007155.6) | Missense Mutation (SNP) | VAF 36/424 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- ABCA12 | c.4242C>T p.H1414= (on ENST00000272895 / NM_173076.3; = p.H1096= on NM_015657.3) | Silent (SNP) | VAF 41/329 reads (12%) | called by muse, mutect2, varscan2
- ABCA2 | c.5199C>T p.V1733= (on ENST00000614293; = p.V1703= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/399 reads (3%) | catalogued as rs992321297, COSV99688260; called by muse, mutect2
- ABCA9 | c.2187G>T p.L729= | Silent (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- ABRAXAS2 | c.129A>T p.S43= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs1564918035; called by muse, mutect2, varscan2
- ADA2 | c.564G>C p.L188= | Silent (SNP) | VAF 21/125 reads (17%) | called by muse, mutect2, varscan2
- AKAP12 | c.207T>A p.A69= | Silent (SNP) | VAF 39/156 reads (25%) | called by muse, mutect2, varscan2
- AKAP9 | c.4398G>T p.G1466= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV62340731; called by muse, mutect2, varscan2
- AL136295.1 | c.1377G>T p.V459= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99938376; called by muse, mutect2, varscan2
- APBA2 | c.498C>T p.P166= | Silent (SNP) | VAF 63/544 reads (12%) | catalogued as COSV101382573; called by muse, mutect2, varscan2
- ASNS | c.165G>A p.P55= | Silent (SNP) | VAF 28/344 reads (8%) | catalogued as rs758717588; called by muse, mutect2
- ATAD3C | c.345C>T p.I115= | Silent (SNP) | VAF 32/452 reads (7%) | called by muse, mutect2
- ATP13A2 | c.1866C>T p.V622= | Silent (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- C7orf25 | c.696A>T p.A232= | Silent (SNP) | VAF 37/247 reads (15%) | catalogued as COSV104416039; called by muse, mutect2, varscan2
- CBLIF | c.228T>C p.T76= | Silent (SNP) | VAF 77/493 reads (16%) | called by muse, mutect2, varscan2
- CCDC22 | c.24C>A p.L8= | Silent (SNP) | VAF 55/217 reads (25%) | catalogued as COSV59905439; called by muse, mutect2, varscan2
- CD8B | c.360G>A p.G120= | Silent (SNP) | VAF 16/170 reads (9%) | catalogued as COSV58925501; called by muse, mutect2
- CELSR3 | c.4206C>T p.F1402= | Silent (SNP) | VAF 20/97 reads (21%) | called by muse, mutect2, varscan2
- CEP192 | c.432C>T p.L144= | Silent (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- CLCN1 | c.2346A>G p.T782= | Silent (SNP) | VAF 45/270 reads (17%) | called by muse, mutect2, varscan2
- CRKL | c.219C>T p.I73= | Silent (SNP) | VAF 54/487 reads (11%) | catalogued as rs780913665; called by muse, mutect2, varscan2
- CST11 | c.297C>A p.T99= | Silent (SNP) | VAF 25/101 reads (25%) | called by muse, mutect2, varscan2
- CYP2C9 | c.1101C>A p.P367= | Silent (SNP) | VAF 22/435 reads (5%) | catalogued as COSV53254340; called by muse, mutect2
- DDHD1 | c.567C>T p.T189= (on ENST00000323669; = p.T386= on NM_030637.3) | Silent (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- DDX59 | c.882G>A p.L294= | Silent (SNP) | VAF 9/188 reads (5%) | called by muse, mutect2
- DERL1 | c.378C>T p.I126= | Silent (SNP) | VAF 11/160 reads (7%) | called by muse, mutect2
- DONSON | c.579A>G p.T193= | Silent (SNP) | VAF 46/236 reads (19%) | called by muse, mutect2, varscan2
- DUSP9 | c.321C>T p.G107= | Silent (SNP) | VAF 52/196 reads (27%) | called by muse, mutect2, varscan2
- FGF23 | c.495C>A p.P165= | Silent (SNP) | VAF 56/303 reads (18%) | called by muse, mutect2, varscan2
- FLG | c.11097G>T p.R3699= | Silent (SNP) | VAF 146/722 reads (20%) | called by muse, mutect2, varscan2
- FLNC | c.2556C>A p.I852= | Silent (SNP) | VAF 55/382 reads (14%) | called by muse, mutect2, varscan2
- FOXR2 | c.585C>T p.L195= | Silent (SNP) | VAF 33/99 reads (33%) | called by muse, mutect2, varscan2
- FPR1 | c.279C>T p.F93= | Silent (SNP) | VAF 91/301 reads (30%) | catalogued as rs374349320, COSV59051119; called by muse, mutect2, varscan2
- FSIP1 | c.990C>T p.L330= | Silent (SNP) | VAF 6/142 reads (4%) | catalogued as rs959918242; called by muse, mutect2
- GLIS3 | c.1137C>T p.F379= | Silent (SNP) | VAF 44/302 reads (15%) | catalogued as rs557850624; called by muse, mutect2, varscan2
- GPR148 | c.51C>A p.A17= | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, varscan2
- GRID2 | c.1407C>A p.G469= | Silent (SNP) | VAF 20/219 reads (9%) | called by muse, mutect2
- HAUS2 | c.174T>A p.A58= | Silent (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- HRNR | c.1620T>C p.S540= | Silent (SNP) | VAF 26/875 reads (3%) | called by muse, mutect2
- HS3ST2 | c.771G>A p.L257= | Silent (SNP) | VAF 36/527 reads (7%) | called by muse, mutect2
- HTT | c.3729G>A p.L1243= | Silent (SNP) | VAF 18/134 reads (13%) | called by muse, mutect2, varscan2
- IGLV3-32 | c.180C>A p.A60= | Silent (SNP) | VAF 82/409 reads (20%) | called by muse, mutect2, varscan2
- IQGAP3 | c.3516G>A p.G1172= | Silent (SNP) | VAF 18/86 reads (21%) | called by muse, mutect2
- IRX4 | c.996C>T p.A332= | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as rs1251847707; called by muse, mutect2, varscan2
- ITIH6 | c.690A>C p.T230= | Silent (SNP) | VAF 39/159 reads (25%) | called by muse, mutect2, varscan2
- KCNJ14 | c.324C>T p.F108= | Silent (SNP) | VAF 27/481 reads (6%) | called by muse, mutect2
- KCNK4 | c.51G>A p.L17= | Silent (SNP) | VAF 33/192 reads (17%) | called by muse, mutect2, varscan2
- LRRC46 | c.471C>A p.A157= | Silent (SNP) | VAF 34/145 reads (23%) | called by muse, mutect2, varscan2
- MAP2K1 | c.1125C>G p.L375= | Silent (SNP) | VAF 70/331 reads (21%) | called by muse, mutect2, varscan2
- MAP3K5 | c.63C>T p.F21= | Silent (SNP) | VAF 14/266 reads (5%) | called by muse, mutect2
- ME1 | c.1038C>A p.S346= | Silent (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- MEX3C | c.735C>G p.A245= | Silent (SNP) | VAF 23/440 reads (5%) | called by muse, mutect2
- MGAM2 | c.2424T>A p.G808= | Silent (SNP) | VAF 11/128 reads (9%) | catalogued as rs376687545; called by muse, mutect2
- MTOR | c.2328G>T p.L776= | Silent (SNP) | VAF 13/330 reads (4%) | called by muse, mutect2
- MUC17 | c.12489C>G p.L4163= | Silent (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- MUC3A | c.8799T>A p.L2933= | Silent (SNP) | VAF 4/87 reads (5%) | called by muse, mutect2
- MUC5B | c.10422C>A p.A3474= | Silent (SNP) | VAF 101/827 reads (12%) | called by muse, mutect2, varscan2
- MYH14 | c.2262C>G p.P754= | Silent (SNP) | VAF 29/267 reads (11%) | called by muse, mutect2, varscan2
- NAALADL2 | c.2124G>A p.L708= | Silent (SNP) | VAF 27/113 reads (24%) | called by muse, mutect2, varscan2
- NHLRC1 | c.357C>T p.T119= | Silent (SNP) | VAF 86/371 reads (23%) | called by muse, varscan2
- NOP53 | c.1014G>A p.T338= | Silent (SNP) | VAF 12/222 reads (5%) | catalogued as rs1341614630; called by muse, mutect2
- NRXN3 | c.2349G>C p.R783= (on ENST00000335750 / NM_001330195.2; = p.R410= on NM_004796.6) | Silent (SNP) | VAF 44/209 reads (21%) | catalogued as COSV59790020; called by muse, mutect2, varscan2
- OR2A4 | c.126G>T p.G42= | Silent (SNP) | VAF 18/416 reads (4%) | catalogued as COSV100199654; called by muse, mutect2
- OR5I1 | c.204A>G p.L68= | Silent (SNP) | VAF 21/100 reads (21%) | called by muse, mutect2, varscan2
- OTOG | c.6426A>T p.P2142= | Silent (SNP) | VAF 27/176 reads (15%) | called by muse, mutect2, varscan2
- PCDHA9 | c.1326T>A p.S442= | Silent (SNP) | VAF 127/598 reads (21%) | called by muse, mutect2, varscan2
- PCDHGA6 | c.2166A>T p.S722= | Silent (SNP) | VAF 93/587 reads (16%) | called by muse, mutect2, varscan2
- PCDHGB2 | c.411G>A p.K137= | Silent (SNP) | VAF 30/134 reads (22%) | called by muse, mutect2, varscan2
- PKD1L2 | c.1959C>T p.L653= | Silent (SNP) | VAF 30/479 reads (6%) | called by muse, mutect2
- PREX1 | c.3426G>T p.G1142= | Silent (SNP) | VAF 123/702 reads (18%) | catalogued as COSV100906011; called by muse, mutect2, varscan2
- PRKDC | c.8673C>A p.R2891= | Silent (SNP) | VAF 43/309 reads (14%) | called by muse, mutect2, varscan2
- PRMT6 | c.774C>G p.L258= | Silent (SNP) | VAF 13/179 reads (7%) | catalogued as rs764614516, COSV100791189; called by muse, mutect2
- PRSS16 | c.309C>A p.G103= | Silent (SNP) | VAF 21/84 reads (25%) | called by muse, mutect2, varscan2
- PRSS33 | c.486C>A p.V162= | Silent (SNP) | VAF 24/118 reads (20%) | called by muse, mutect2, varscan2
- PSG4 | c.1002C>T p.L334= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV99737416; called by muse, mutect2, varscan2
- PWWP3A | c.1819C>T p.L607= (on ENST00000627377; = p.L606= on NM_032853.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 41/267 reads (15%) | catalogued as COSV60904586; called by muse, mutect2, varscan2
- RELN | c.801C>A p.S267= | Silent (SNP) | VAF 13/134 reads (10%) | catalogued as COSV59034485; called by muse, mutect2, varscan2
- RGS22 | c.432C>A p.A144= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- RNF217 | c.873G>A p.L291= | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- RSPO1 | c.505C>A p.R169= | Silent (SNP) | VAF 41/371 reads (11%) | catalogued as COSV100740463; called by muse, mutect2, varscan2
- SALL3 | c.1362G>T p.G454= | Silent (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- SEC14L5 | c.615C>T p.A205= | Silent (SNP) | VAF 21/146 reads (14%) | called by muse, mutect2, varscan2
- SERPINA9 | c.447G>A p.L149= | Silent (SNP) | VAF 75/522 reads (14%) | called by muse, mutect2, varscan2
- SLC20A2 | c.993C>T p.F331= | Silent (SNP) | VAF 34/177 reads (19%) | called by muse, mutect2, varscan2
- SLC25A22 | c.537G>T p.R179= | Silent (SNP) | VAF 43/288 reads (15%) | called by muse, mutect2, varscan2
- SPRY2 | c.246C>A p.L82= | Silent (SNP) | VAF 22/256 reads (9%) | called by muse, mutect2
- STARD9 | c.9936C>T p.F3312= | Silent (SNP) | VAF 42/257 reads (16%) | catalogued as rs1275648655; called by muse, mutect2, varscan2
- TAS1R2 | c.2328C>G p.L776= | Silent (SNP) | VAF 146/1006 reads (15%) | catalogued as COSV64743440; called by muse, mutect2, varscan2
- TBC1D4 | c.1413C>A p.L471= | Silent (SNP) | VAF 30/221 reads (14%) | catalogued as COSV66489938; called by muse, mutect2, varscan2
- TBX5 | c.669G>C p.T223= | Silent (SNP) | VAF 42/302 reads (14%) | catalogued as COSV59863244; called by muse, mutect2, varscan2
- TERT | c.2874C>G p.L958= | Silent (SNP) | VAF 34/532 reads (6%) | catalogued as COSV57206958; called by muse, mutect2
- THADA | c.4107C>T p.A1369= | Silent (SNP) | VAF 22/165 reads (13%) | catalogued as rs374526686; called by muse, mutect2, varscan2
- TMEM235 | c.69C>A p.A23= | Silent (SNP) | VAF 42/167 reads (25%) | called by muse, mutect2, varscan2
- TRAV36DV7 | c.25C>T p.L9= | Silent (SNP) | VAF 16/172 reads (9%) | called by muse, mutect2
- TRIM28 | c.1674G>T p.T558= | Silent (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- TRPC5 | c.618C>T p.P206= | Silent (SNP) | VAF 17/181 reads (9%) | catalogued as COSV99460673; called by muse, mutect2
- TSHZ3 | c.357G>A p.K119= | Silent (SNP) | VAF 28/179 reads (16%) | called by muse, mutect2, varscan2
- TSSK3 | c.441G>C p.L147= | Silent (SNP) | VAF 42/350 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.58824G>A p.V19608= (on ENST00000591111; = p.V12184= on NM_003319.4) | Silent (SNP) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- TTN | c.51246A>G p.P17082= (on ENST00000591111; = p.P9658= on NM_003319.4) | Silent (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- TTN | c.25212G>T p.V8404= (on ENST00000591111; = p.V7477= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/44 reads (11%) | called by mutect2, varscan2
- TTN | c.11112C>A p.T3704= (on ENST00000591111; = p.T3658= on NM_003319.4) | Silent (SNP) | VAF 22/135 reads (16%) | called by muse, mutect2, varscan2
- TYMP | c.381G>C p.L127= | Silent (SNP) | VAF 90/538 reads (17%) | called by muse, mutect2, varscan2
- UBR4 | c.9018C>T p.L3006= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as COSV100920751; called by muse, mutect2
- UGT3A2 | c.597C>T p.G199= | Silent (SNP) | VAF 13/402 reads (3%) | called by muse, mutect2
- UNC80 | c.2001C>T p.D667= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs1205558028; called by muse, varscan2
- USH2A | c.14911C>A p.R4971= | Silent (SNP) | VAF 63/289 reads (22%) | catalogued as CM1110189, COSV56364393; called by muse, mutect2, varscan2
- ZCCHC2 | c.90C>A p.G30= | Silent (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2, varscan2
- ZNF543 | c.27G>A p.V9= | Silent (SNP) | VAF 64/234 reads (27%) | called by muse, mutect2, varscan2
- ZRANB1 | c.1491C>T p.S497= | Silent (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2
- ABLIM2 | c.1169-116G>T | Intron (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- AC006486.1 | c.23-3068C>T | Intron (SNP) | VAF 97/350 reads (28%) | catalogued as rs547169672; called by muse, mutect2, varscan2
- AGPAT4 | c.348+591T>G | Intron (SNP) | VAF 21/176 reads (12%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824644 T>C | 5'Flank (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- APBA2 | c.*19C>A | 3'UTR (SNP) | VAF 27/248 reads (11%) | called by muse, mutect2
- AVPR2 | chrX:153905056 G>C | 5'Flank (SNP) | VAF 34/112 reads (30%) | called by muse, mutect2, varscan2
- C22orf34 | n.197G>T | RNA (SNP) | VAF 53/207 reads (26%) | catalogued as rs1419110485; called by muse, mutect2, varscan2
- CCDC74B | c.296-389C>A | Intron (SNP) | VAF 55/503 reads (11%) | catalogued as rs1236199291; called by muse, mutect2, varscan2
- CEND1 | chr11:783719 C>T | 3'Flank (SNP) | VAF 7/34 reads (21%) | catalogued as rs1052936087; called by muse, mutect2, varscan2
- CHAT | c.1512-9C>G | Intron (SNP) | VAF 24/153 reads (16%) | called by muse, mutect2, varscan2
- CHST6 | c.*15G>T | 3'UTR (SNP) | VAF 28/307 reads (9%) | called by muse, mutect2
- CKM | c.-6G>T | 5'UTR (SNP) | VAF 48/182 reads (26%) | catalogued as COSV55532843; called by muse, mutect2, varscan2
- CLEC7A | c.202+315A>G | Intron (SNP) | VAF 18/110 reads (16%) | called by muse, mutect2, varscan2
- CSNK1D | c.76+92del | Intron (DEL) | VAF 12/99 reads (12%) | called by mutect2, pindel, varscan2
- DBF4B | c.1189+208G>T | Intron (SNP) | VAF 101/374 reads (27%) | called by muse, mutect2, varscan2
- DRC1 | c.679-163C>A | Intron (SNP) | VAF 27/125 reads (22%) | called by muse, mutect2, varscan2
- ETV1 | c.181+385G>T | Intron (SNP) | VAF 36/164 reads (22%) | catalogued as rs559142802, COSV99623517; called by muse, mutect2, varscan2
- EYA1 | c.1200-13T>A | Intron (SNP) | VAF 42/249 reads (17%) | called by muse, mutect2, varscan2
- FAM90A27P | n.219T>G | RNA (SNP) | VAF 10/204 reads (5%) | catalogued as rs1448897979; called by muse, mutect2
- FHL2 | c.157-4356G>T | Intron (SNP) | VAF 28/219 reads (13%) | called by muse, mutect2, varscan2
- GCK | c.46-4673C>A | Intron (SNP) | VAF 22/163 reads (13%) | catalogued as COSV61755459; called by muse, mutect2, varscan2
- GRHPR | c.865+23C>G | Intron (SNP) | VAF 46/355 reads (13%) | called by muse, mutect2, varscan2
- IKBKB | c.692+509C>G | Intron (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- ITGB1BP2 | c.65-16C>G | Intron (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- KLF6 | c.*1070G>A | 3'UTR (SNP) | VAF 12/131 reads (9%) | called by muse, mutect2
- KLF7 | c.102+16282C>T | Intron (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- KRT8P11 | n.546G>T | RNA (SNP) | VAF 41/250 reads (16%) | called by muse, mutect2, varscan2
- LCMT1 | c.114-2356G>T | Intron (SNP) | VAF 7/135 reads (5%) | called by muse, mutect2
- LYPLA1 | c.*2G>A | 3'UTR (SNP) | VAF 4/30 reads (13%) | catalogued as rs1421400786; called by muse, mutect2, varscan2
- MBD5 | c.2845+459G>T | Intron (SNP) | VAF 19/114 reads (17%) | called by muse, mutect2, varscan2
- MIR6511A1 | chr16:14929373 A>T | 3'Flank (SNP) | VAF 66/1962 reads (3%) | called by muse, mutect2
- NDUFB4 | c.*18A>G | 3'UTR (SNP) | VAF 9/40 reads (23%) | catalogued as rs746463863; called by muse, mutect2, varscan2
- NDUFS2 | c.1116+32G>T | Intron (SNP) | VAF 39/173 reads (23%) | called by muse, mutect2, varscan2
- NGRN | chr15:90275631 G>T | 3'Flank (SNP) | VAF 52/328 reads (16%) | called by muse, mutect2, varscan2
- OR5AK4P | n.364G>C | RNA (SNP) | VAF 16/133 reads (12%) | called by muse, mutect2, varscan2
- OTUD7A | c.550+62A>T | Intron (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- PPIAP15 | chr3:109476750 G>T | 5'Flank (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
- PRDM1 | c.-1G>C | 5'UTR (SNP) | VAF 7/144 reads (5%) | called by muse, mutect2
- RHAG | c.*37C>G | 3'UTR (SNP) | VAF 32/546 reads (6%) | called by muse, mutect2
- SLC8A1 | c.1915+626G>T | Intron (SNP) | VAF 17/94 reads (18%) | called by muse, mutect2, varscan2
- SMIM11P1 | n.41T>A | RNA (SNP) | VAF 18/85 reads (21%) | called by muse, mutect2, varscan2
- SNORD116-26 | n.27G>C | RNA (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- SNX29 | c.-29G>T | 5'UTR (SNP) | VAF 14/202 reads (7%) | catalogued as COSV104440692; called by muse, mutect2
- SPDYC | c.*17G>C | 3'UTR (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- SSPOP | n.9432C>A | RNA (SNP) | VAF 10/197 reads (5%) | catalogued as COSV100947236; called by muse, mutect2
- SYNE2 | c.17236-985C>T | Intron (SNP) | VAF 19/184 reads (10%) | called by muse, mutect2, varscan2
- TANK | c.1101+1192C>A | Intron (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- TMEM26 | c.682+494C>A | Intron (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- TMPRSS7 | c.731-301T>G | Intron (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- TRPM4 | c.3641-21C>G | Intron (SNP) | VAF 20/548 reads (4%) | catalogued as rs1347083636; called by muse, mutect2
- TSPYL1 | c.-29C>T | 5'UTR (SNP) | VAF 36/372 reads (10%) | catalogued as rs1230924609, COSV100889567; called by muse, mutect2
- TTR | c.*40G>T | 3'UTR (SNP) | VAF 39/357 reads (11%) | catalogued as rs189110724; called by muse, mutect2, varscan2
- TUSC3 | c.1028+51G>T | Intron (SNP) | VAF 28/111 reads (25%) | called by muse, mutect2, varscan2
- UBBP4 | n.587G>T | RNA (SNP) | VAF 150/718 reads (21%) | called by muse, mutect2, varscan2
- ZNF12 | c.-481C>G | 5'UTR (SNP) | VAF 16/222 reads (7%) | called by muse, mutect2
- ZNF273 | c.103-523C>T | Intron (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
